National Lung Screening Trial (NLST) participant 111621 — screening results and CT findings
Open-access record from the public subset of National Lung Screening Trial clinical data distributed by the NCI Imaging Data Commons (release v24, collection nlst). NLST enrolled current and former heavy smokers aged 55–74 in 2002–2004 and randomised them to three annual screens (T0, T1, T2) with low-dose CT or chest radiography, with follow-up through 2009. Coded values are written out from the NLST data dictionaries; day counts are days from randomisation.
https://doi.org/10.7937/TCIA.HMQ8-J677

Participant
Age at randomisation: 65 years; Gender: female; Race: White; Cigarette smoking status at randomisation: former smoker (to be eligible, former smokers had quit within the previous 15 years); Enrolled through a Lung Screening Study (LSS) centre (from the participant ID range).

Screening results (official result of each annual screen after comparison with prior images; this participant has CT screening exam records, so these are low-dose CT screens)
- T0 (day 85): Positive, change unspecified: nodule(s) >= 4 mm or enlarging nodule(s), mass(es), or other non-specific abnormalities suspicious for lung cancer. Exam quality: diagnostic CT; technique as recorded on the form: 120 kVp, 80 mA, 43 effective mAs, display field of view 31 cm, reconstruction filter GE Standard / GE Bone.
- T1 (day 438): Negative screen, minor abnormalities not suspicious for lung cancer. Exam quality: diagnostic CT; technique as recorded on the form: 120 kVp, 80 mA, 46 effective mAs, display field of view 31 cm, reconstruction filter GE Standard / GE Bone.
- T2 (day 795): Negative screen, minor abnormalities not suspicious for lung cancer. Exam quality: diagnostic CT; technique as recorded on the form: 120 kVp, 80 mA, 46 effective mAs, display field of view 31 cm, reconstruction filter GE Standard / GE Bone.

Abnormalities recorded by the reading radiologist on the CT screens (13 abnormalities; numbered within each screening year; size, margins, attenuation and location were collected only for non-calcified nodules or masses of at least 4 mm; interval-change items come from the comparison read)
- T0 abnormality 1: Non-calcified nodule or mass (opacity >= 4 mm diameter); epicentre in the left lower lobe; longest diameter 10 mm, longest perpendicular diameter 10 mm; margins poorly defined; predominant attenuation ground glass; greatest diameter on CT slice 111.
- T0 abnormality 2: Non-calcified nodule or mass (opacity >= 4 mm diameter); epicentre in the left lower lobe; longest diameter 4 mm, longest perpendicular diameter 4 mm; margins smooth; predominant attenuation soft tissue; greatest diameter on CT slice 86.
- T0 abnormality 3: Non-calcified nodule or mass (opacity >= 4 mm diameter); epicentre in the right lower lobe; longest diameter 4 mm, longest perpendicular diameter 3 mm; margins spiculated (stellate); predominant attenuation soft tissue; greatest diameter on CT slice 47.
- T0 abnormality 4: Non-calcified hilar/mediastinal adenopathy or mass (>= 10 mm on short axis).
- T0 abnormality 5: Other minor abnormality noted.
- T0 abnormality 6: Benign lung nodule(s) (benign calcification).
- T1 abnormality 1: Benign lung nodule(s) (benign calcification).
- T1 abnormality 2: Other minor abnormality noted.
- T1 abnormality 3: Non-calcified hilar/mediastinal adenopathy or mass (>= 10 mm on short axis).
- T2 abnormality 1: Benign lung nodule(s) (benign calcification).
- T2 abnormality 2: Other minor abnormality noted.
- T2 abnormality 3: Non-calcified hilar/mediastinal adenopathy or mass (>= 10 mm on short axis).
- T2 abnormality 4: Reticular/reticulonodular opacities, honeycombing, fibrosis, scar.

Follow-up
No confirmed lung cancer during the trial; Last known free of lung cancer: day 2,187.
